Gene-level copy-number profile of tumor specimen TCGA-D3-A5GR-06A from TCGA case TCGA-D3-A5GR, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 37.4 years (13,645 days).
Specimen TCGA-D3-A5GR-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.60c7f826-ae72-463f-9cdb-8c8847cc5c1e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A5GR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5eb5ae3-137d-4de0-a2ff-07444a475c1c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 8,919; copy number 2: 42,474; copy number 3: 5,198; copy number 4: 3,192; copy number 17: 4; copy number 32: 3; copy number 38: 5; copy number 63: 1; copy number 66: 4; copy number 70: 2.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr3:116,645,902–117,027,039, 8 genes: BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:30,151,886–30,160,592, 2 genes, copy number 70: LINC00384, LINC00385.
- chr13:30,296,147–30,429,758, 7 genes, copy number 32–66: PRDX2P1, LINC00427, LINC00426, AL356750.1, AL161893.1, LINC01058, UBE2L5.
- chr13:72,703,693–72,756,198, 4 genes, copy number 17: RPL21P110, RNU6-80P, MZT1, BORA.
- chr13:74,552,503–74,565,445, 1 gene, copy number 63: LINC00347.
- chr13:113,262,920–113,364,148, 5 genes, copy number 38 (within-gene range 1–38): MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1.

Autosomal genes at a single copy (total copy number 1): 8,919. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
